Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5885, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5885-01A (Primary Tumor).

[page 1 of 3]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

1305885

Clinical Diagnosis & History:

Patient with left renal mass history of DM, obesity, HTN.

Specimens Submitted:

1. SP: Kidney, left, radical nephrectomy
2. SP: Lymph nodes, para-aortic and preaortic, excision
3. SP: Adrenal and suprahilar lymph nodes, Left, resection

DIAGNOSIS:

1. SP: Kidney, left, radical nephrectomy

Two discrete tumor masses are identified:

a. High grade renal cell carcinoma with extensive tubular and tubulopapillary architecture, favored to be a tumor of distal nephron origin; see comment.

- The tumor measures 7.1 cm
- Local invasion: not identified
- Renal vein invasion: not identified
- Surgical margins: free of tumor
- Adrenal gland: not identified (see Part 3)
- Lymph nodes: not identified
- Non-neoplastic kidney: unremarkable
- Pathologic Stage: pT2 (tumor > 7.0 cm in greatest dimension limited to the kidney)

Comment: The tumor demonstrates marked cytologic atypia in the form of nucleio- and nucleolomegaly, as well as focal desmoplasia. Immunohistochemical stains are positive for CK7 (focal, strong), Racemase (diffuse, strong), c-kit (patchy, moderate), and CA-IX (focal, weak), while negative for 34BE12. Although the growth pattern of this tumor is unusual, its range of features is felt to be most compatible with a distal nephron/collecting duct tumor. This case has been reviewed with the [redacted] which concurs with the diagnosis.

b. Renal cell carcinoma, clear cell (conventional) type, Fuhrman nuclear grade II/IV

- The tumor measures 2.6 cm
- Local invasion: tumor invades through the renal capsule but is confined within Gerota's fascia
- Renal vein invasion: not identified
- Surgical margins: free of tumor
- Adrenal gland: not identified (see Part 3)
- Lymph nodes: not identified
- Non-neoplastic kidney: unremarkable
- Pathologic Stage: pT3 (tumor invades peri-nephric tissues but not beyond Gerota's fascia)

2. SP: Lymph nodes, para-aortic and preaortic, excision

Lymph Nodes:

Not involved

Number of nodes examined: 15

3. SP: Adrenal and suprahilar lymph nodes, left, resection

Benign adrenal gland.

[page 2 of 3]
[REDACTED]

No lymph nodes identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result

Special Stain

Comment

RECUT

CK7

RACEMASE

34BE12

CA-1X.

CD117

NEG CONT

IMM RECUT

Gross Description:

[REDACTED]

1). The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1174 g in total. The entire specimen measures 25 x 13.5 x 7.5 cm. The kidney measures 13.5 x 6 x 5.5 cm. The attached ureter measures 7.5 cm in length and 2.4 cm in diameter. The attached renal vein measures 0.9 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. No adrenal gland identified. The kidney is inked black and bivalved to reveal two masses. The first mass is a well-circumscribed white tan mass arising from the middle pole of the kidney measuring 7.1 x 7 x 3.2 cm. The mass shows areas of necrosis and hemorrhage. The mass is partially encapsulated and is abutting the pelvis but does not grossly involve it. The mass appears to bulge into the perirenal fat but appears to be contained within the capsule. There is no gross extension into the perihilar fat. The second mass is located in the lower pole of the kidney, measuring 2.6 x 2 x 1.6 cm, the mass is yellow orange and lobulated, and appears to invade the perirenal fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

TU -- tumor

THF -- tumor with hilar fat

THS -- tumor with sinus fat

TK -- tumor with adjacent kidney

TP -- tumor to renal pelvis

K -- uninvolved kidney

M2 -- representative section of the second mass

M2F -- second mass with perirenal fat

ADDM2 -- additional second mass with radial margin

[REDACTED]

2). The specimen is received in formalin labeled "paraortic and preaortic lymph nodes" and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 2.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN1- sectioned largest lymph node

BLN-bisected lymph nodes

LN-lymph nodes

[REDACTED]

[page 3 of 3]
2). The specimen is received fresh labeled "left adrenal and suprahilar lymph nodes". The specimen consists of the adrenal gland with surrounding adipose tissue weighing 70 g, and measures 10 x 5 x 3.5 cm. The entire outer surface is inked blue. The specimen is serially sectioned and shows unremarkable parenchyma, with thin yellow orange cortex and brown medulla. No grossly identifiable lesion. Representative sections of the adrenal gland are submitted. Possible lymph nodes are submitted.

Summary of sections:

A -- adrenal gland

PLN -- possible lymph nodes

Summary of Sections:

Part 1: SP: Kidney, left, radical nephrectomy

Block	Sect. Site	PCs
1	ADDM2	1
1	K	1
2	M2	2
1	M2F	1
1	THF	1
1	THS	1
1	TK	1
2	TP	2
5	TU	5
1	UVM	1

Part 2: SP: Lymph nodes, para-aortic and preaortic, excision

Block	Sect. Site	PCs
5	bln	5
4	ln	4
3	ln1	3

Part 3: SP: Adrenal and suprahilar lymph nodes, Left, resection

Block	Sect. Site	PCs
2	A	2
2	PLN	2

Source: NCI Genomic Data Commons file cc1679a0-01af-4bb1-82aa-095be1c2f85b (TCGA-BQ-5885.2C551C8B-4911-4541-89BF-814FEF2233CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).